Gene-level copy-number profile of tumor specimen HCM-SANG-1321-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-1321-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1321-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ffeb608b-0d74-48d8-b66b-d03f1f3b9d9e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1321-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/17d8e79e-8dfb-42e4-b4db-db404e0f2b45

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 11,055; copy number 2: 39,739; copy number 3: 5,749; copy number 4: 329; copy number 5: 1,544; copy number 6: 429; copy number 7: 31; copy number 12: 4.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:29,488,193–30,860,254, 17 genes: AL671862.1, AC092265.1, AL645944.1, LINC01648, AL137076.1, AL021921.1, AL161638.2, AL161638.1, MATN1, MATN1-AS1, AL137857.1, LAPTM5, MIR4420, AL137027.1, LINC01778, RN7SKP91, AL445235.1.
- chr3:44,115,818–44,122,365, 2 genes: AC006058.4, AC006058.1.
- chr15:101,803,509–101,820,197, 2 genes: OR4F6, OR4F15.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,008 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:38,699,274–145,066,685, 1,611 genes, copy number 5–7 (broad region; genes not listed).
- chr10:38,783,004–38,783,108, 1 gene, copy number 6: AL590623.1.
- chr20:30,484,925–38,578,859, 266 genes, copy number 5–12 (broad region; genes not listed).
- chr20:44,302,840–47,656,877, 130 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,199. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
